Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6EY, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6EY-01A (Primary Tumor).

ICD O-3
Adenocarcinoma, tubular 8211/3
Site GCF Gastric antrum C16.3
path Pylorus C16.4
JW 6/25/13

Department of Cancer Pathology

Patient: XXX

Age

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer.**

Date of admission:

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Stomach adenocarcinoma, tubular and poorly differentiated (G3, pT2, pN2). Signs of vascular invasion. (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

The specimen consisting of the stomach, after being incised along the greater curvature, sized 18,8x14,7 cm with the omentum sized 20.8x20.1cm.

Tumour sized 7.8x6.4x1.3 cm in the pyloric region.

Distance from the proximal end: 7.2cm, from distal end: 1.6cm.

Microscopic description:

Gastric adenocarcinoma (tubular type, partly poorly differentiated G3 - intestinal type acc. to Lauren); the tumour infiltrates the whole thickness of the stomach wall and fat tissue of the curvature.

Excision lines free of neoplastic lesions.

Cancer metastases to lymph nodes (13/18).

Signs of massive vascular invasion.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file f495e9fd-b848-4058-9141-042be11c99fd (TCGA-D7-A6EY.0B0F87C3-A67F-423C-B940-76698B1DE632.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).